Somatic mutation profile of cancer-model specimen HCM-CSHL-0191-C25-85A (3D Organoid; aliquot HCM-CSHL-0191-C25-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0191-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 75.5 years (27,561 days).
Specimen HCM-CSHL-0191-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0944e9ae-7c69-4ef2-8c17-f7995df6f8ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0191-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0191-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f67d90e-1e95-49d4-946d-6956e4fa3b0c

The open-access MAF lists 84 somatic variants for this specimen: 50 protein-altering or splice-affecting, 20 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 20, Intron 7, Splice Region 3, Nonsense Mutation 2, RNA 2, 3'Flank 2, 3'UTR 1, 5'Flank 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.645T>A p.S215R | Missense Mutation (SNP) | VAF 158/160 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD941799, COSV52752255, COSV52783847, COSV52798196; called by muse, mutect2, varscan2
- ABCA13 | c.12925C>T p.R4309C | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.398); catalogued as rs763439416, COSV68949713; called by muse, mutect2, varscan2
- AHNAK2 | c.9820A>G p.M3274V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772239379; called by mutect2, varscan2
- APOB | c.13154G>A p.R4385H | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs533755016, CM055088, COSV51925197; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CAPN15 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs749018970; called by muse, mutect2, varscan2
- CTDSP2 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs767635273; called by muse, mutect2, varscan2
- DNAH7 | c.10777C>T p.R3593W | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200008102, COSV100415379; called by muse, mutect2, varscan2
- FAM189A1 | c.1230C>T p.G410= | Splice Region (SNP) | VAF 27/181 reads (15%) | catalogued as rs1318028148, COSV54268486; called by muse, mutect2, varscan2
- GIMAP8 | c.826G>T p.G276* | Nonsense Mutation (SNP) | VAF 53/254 reads (21%) | catalogued as COSV56233018; called by muse, mutect2, varscan2
- GRM1 | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 77/321 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs746003735; called by muse, mutect2, varscan2
- HIVEP2 | c.3244C>T p.R1082W | Missense Mutation (SNP) | VAF 103/349 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs949143984, COSV50006082; called by muse, mutect2, varscan2
- HOXD10 | c.350C>G p.S117C | Missense Mutation (SNP) | VAF 65/280 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV50898894; called by muse, mutect2, varscan2
- HTT | c.3753G>A p.K1251= | Splice Region (SNP) | VAF 26/97 reads (27%) | catalogued as COSV100751122; called by muse, mutect2, varscan2
- MAGEC2 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748232460, COSV55998335, COSV56000976; called by muse, varscan2
- MUC4 | c.7994T>C p.V2665A | Missense Mutation (SNP) | VAF 30/452 reads (7%) | SIFT tolerated, low confidence (0.44); catalogued as rs201101114; called by muse, varscan2
- MYH13 | c.1955C>T p.S652L | Missense Mutation (SNP) | VAF 48/48 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs780897551; called by muse, mutect2, varscan2
- NFKBIL1 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 110/155 reads (71%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.892); catalogued as rs769052971; called by muse, mutect2, varscan2
- OGFOD2 | c.218G>A p.R73Q (on ENST00000228922 / NM_001304833.1; = p.R13Q on NM_024623.3) | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs371221631; called by muse, mutect2, varscan2
- OPRL1 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 63/291 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.146); catalogued as rs776959612, COSV61092246; called by muse, mutect2, varscan2
- RRP12 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs183677741; called by muse, mutect2, varscan2
- SEMA6C | c.2336C>T p.P779L | Missense Mutation (SNP) | VAF 65/270 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.035); catalogued as rs1473303306; called by muse, mutect2, varscan2
- SLC25A1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 99/310 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs781929221; called by muse, mutect2, varscan2
- SYNJ1 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 61/89 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs547450707, COSV100449248; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TXNDC2 | c.364G>T p.A122S (on ENST00000306084 / NM_001098529.2; = p.A55S on NM_032243.6) | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1408953657; called by muse, mutect2, varscan2
- ZDBF2 | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 274/360 reads (76%) | SIFT tolerated (0.23); PolyPhen benign (0.145); catalogued as COSV65630257; called by muse, mutect2, varscan2
- ZFC3H1 | c.4565G>A p.R1522Q | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs762358615, COSV66437108; called by muse, mutect2, varscan2
- ABI3BP | c.1502-4C>A | Splice Region (SNP) | VAF 60/85 reads (71%) | called by muse, varscan2
- C1S | c.1175A>G p.Y392C | Missense Mutation (SNP) | VAF 322/538 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.062); called by muse, varscan2
- CDCA7 | c.131A>G p.D44G | Missense Mutation (SNP) | VAF 53/76 reads (70%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDH22 | c.2201del p.P734Rfs*170 | Frame Shift Del (DEL) | VAF 46/217 reads (21%) | called by mutect2, pindel, varscan2
- CSF1R | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 162/435 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FMR1 | c.1070A>G p.D357G | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GLI1 | c.1340C>A p.S447Y | Missense Mutation (SNP) | VAF 135/234 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- GRIK3 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 23/148 reads (16%) | called by muse, mutect2, varscan2
- KIT | c.164G>T p.R55M | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- KLHL23 | c.1040A>C p.D347A | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- LDB2 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 101/155 reads (65%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LPCAT2 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 71/82 reads (87%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- LYST | c.868A>C p.T290P | Missense Mutation (SNP) | VAF 41/302 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MIB2 | c.475A>T p.S159C | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MPHOSPH9 | c.2917G>A p.E973K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYO9B | c.1055A>T p.E352V | Missense Mutation (SNP) | VAF 74/133 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- PARPBP | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PIKFYVE | c.3998G>T p.W1333L | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PLEKHO1 | c.807C>G p.C269W | Missense Mutation (SNP) | VAF 131/224 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTPRN | c.1586A>G p.D529G | Missense Mutation (SNP) | VAF 131/258 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- SIPA1L1 | c.2893G>C p.G965R | Missense Mutation (SNP) | VAF 115/116 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAAR2 | c.178G>C p.G60R (on ENST00000367931 / NM_001033080.1; = p.G15R on NM_014626.3) | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TDRD15 | c.1219A>G p.T407A | Missense Mutation (SNP) | VAF 127/172 reads (74%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USP39 | c.174C>G p.S58R | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ACAN | c.1947C>T p.G649= | Silent (SNP) | VAF 111/271 reads (41%) | catalogued as rs377391149; called by muse, mutect2, varscan2
- ACE | c.2025C>T p.N675= | Silent (SNP) | VAF 40/362 reads (11%) | catalogued as rs773535888; called by muse, mutect2, varscan2
- AHNAK2 | c.9636A>G p.P3212= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs188776055; called by muse, varscan2
- BCL11B | c.1245C>T p.G415= (on ENST00000357195 / NM_001282237.2; = p.G344= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 128/223 reads (57%) | catalogued as rs769200328, COSV61738390; called by muse, mutect2, varscan2
- CALD1 | c.2136C>A p.I712= (on ENST00000361675 / NM_033138.4; = p.I457= on NM_004342.7) | Silent (SNP) | VAF 64/184 reads (35%) | called by muse, mutect2, varscan2
- CARD9 | c.1275C>T p.S425= | Silent (SNP) | VAF 63/283 reads (22%) | catalogued as rs776362712; called by muse, mutect2, varscan2
- CCDC114 | c.1590C>T p.T530= | Silent (SNP) | VAF 59/167 reads (35%) | catalogued as rs908877525, COSV59557755; called by muse, mutect2, varscan2
- FAT3 | c.12474C>T p.I4158= | Silent (SNP) | VAF 68/275 reads (25%) | catalogued as rs1478000445, COSV53144510; called by muse, mutect2, varscan2
- GABRA1 | c.396G>A p.K132= | Silent (SNP) | VAF 100/264 reads (38%) | catalogued as COSV50099491, COSV50101391; called by muse, mutect2, varscan2
- IRX5 | c.1062C>T p.N354= | Silent (SNP) | VAF 31/125 reads (25%) | catalogued as rs774276733; called by muse, mutect2, varscan2
- JMJD8 | c.126C>A p.R42= | Silent (SNP) | VAF 107/398 reads (27%) | catalogued as rs756158670; called by muse, mutect2, varscan2
- KBTBD4 | c.1419C>T p.N473= | Silent (SNP) | VAF 75/314 reads (24%) | catalogued as rs888010650; called by muse, mutect2, varscan2
- MUC12 | c.7944A>G p.T2648= (on ENST00000379442; = p.T2505= on NM_001164462.1) | Silent (SNP) | VAF 78/442 reads (18%) | catalogued as rs1342253299, COSV65182302; called by mutect2, varscan2
- MUC12 | c.11193A>G p.T3731= (on ENST00000379442; = p.T3588= on NM_001164462.1) | Silent (SNP) | VAF 329/2920 reads (11%) | catalogued as rs771904256; called by muse, varscan2
- NFKB2 | c.2487A>G p.A829= | Silent (SNP) | VAF 61/183 reads (33%) | called by muse, mutect2, varscan2
- PCDHB16 | c.1965C>T p.T655= | Silent (SNP) | VAF 400/792 reads (51%) | catalogued as rs782521205; called by muse, mutect2, varscan2
- ST8SIA4 | c.294C>G p.V98= | Silent (SNP) | VAF 28/173 reads (16%) | called by muse, mutect2, varscan2
- TPCN1 | c.360G>A p.L120= | Silent (SNP) | VAF 108/206 reads (52%) | catalogued as COSV100136294; called by muse, mutect2, varscan2
- ZNF385D | c.90G>A p.S30= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as rs747950100, COSV55747416; called by muse, mutect2, varscan2
- ZNF518B | c.2133C>T p.N711= | Silent (SNP) | VAF 66/203 reads (33%) | catalogued as rs766040632, COSV58722070, COSV58722183; called by muse, mutect2, varscan2
- ABI3BP | c.1576+4344C>G | Intron (SNP) | VAF 52/84 reads (62%) | catalogued as COSV52531383; called by muse, varscan2
- AP000769.5 | chr11:65499134 del AT | 5'Flank (DEL) | VAF 42/213 reads (20%) | catalogued as rs1491393910; called by mutect2, pindel, varscan2
- APBA2 | c.-8C>T | 5'UTR (SNP) | VAF 83/362 reads (23%) | catalogued as rs765516950, COSV101382621; called by muse, mutect2, varscan2
- CFAP410 | c.144-990G>T | Intron (SNP) | VAF 56/236 reads (24%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40546411 C>A | 3'Flank (SNP) | VAF 37/109 reads (34%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1099119 A>G | 3'Flank (SNP) | VAF 113/476 reads (24%) | called by muse, varscan2
- OPA1 | c.2983+1201C>T | Intron (SNP) | VAF 119/362 reads (33%) | called by muse, mutect2, varscan2
- OR7E5P | n.653G>A | RNA (SNP) | VAF 52/186 reads (28%) | catalogued as rs768970957; called by muse, mutect2, varscan2
- PIPSL | n.994C>T | RNA (SNP) | VAF 118/392 reads (30%) | catalogued as rs760368183; called by muse, mutect2, varscan2
- PTPN6 | c.8+19C>T | Intron (SNP) | VAF 238/396 reads (60%) | catalogued as rs782087979; called by muse, mutect2, varscan2
- UMPS | c.*2779G>A | 3'UTR (SNP) | VAF 97/273 reads (36%) | called by muse, mutect2, varscan2
- UQCC1 | c.130-2184A>G | Intron (SNP) | VAF 24/116 reads (21%) | called by muse, mutect2, varscan2
- VAPB | c.396+29G>T | Intron (SNP) | VAF 20/117 reads (17%) | called by muse, mutect2, varscan2
- VAPB | c.396+30A>T | Intron (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2, varscan2
